Somatic mutation profile of tumor specimen TCGA-66-2768-01A (aliquot TCGA-66-2768-01A-01W-0877-08) from TCGA case TCGA-66-2768, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 57.4 years (20,970 days).
Specimen TCGA-66-2768-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87d85343-a9ad-44af-8861-bd68ca4b05b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2768-11A (Solid Tissue Normal), aliquot TCGA-66-2768-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/297134e8-2068-4842-9cf5-7ce3625b964d

The open-access MAF lists 305 somatic variants for this specimen: 238 protein-altering or splice-affecting, 62 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 193, Silent 62, Nonsense Mutation 20, Frame Shift Del 10, Splice Site 5, Splice Region 5, Frame Shift Ins 4, RNA 3, Intron 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 52/134 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55945514; called by muse, mutect2, varscan2
- ABLIM2 | c.388A>T p.M130L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV56400394; called by muse, mutect2, varscan2
- ABRA | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs200193774, COSV61731940; called by muse, mutect2, varscan2
- ACP2 | c.331C>G p.L111V | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57041760; called by muse, mutect2, varscan2
- AHCY | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.719); catalogued as rs765418686, COSV54152534; called by muse, mutect2, varscan2
- AHDC1 | c.2648G>A p.R883Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs202145401, COSV55936877, COSV99899531; called by muse, mutect2, varscan2
- AMPH | c.1759G>C p.E587Q | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.38); catalogued as COSV57733507; called by muse, mutect2, varscan2
- ARHGAP30 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as COSV100920152; called by muse, mutect2, varscan2
- ASB5 | c.187C>G p.Q63E | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.249); catalogued as rs143631688; called by muse, mutect2, varscan2
- AZGP1 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 87/426 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs377632165; called by muse, mutect2
- BAZ1B | c.4015C>T p.R1339W | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59988791; called by muse, mutect2, varscan2
- BEND4 | c.1319del p.S440* | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | catalogued as COSV101549716; called by mutect2, pindel, varscan2
- BOD1L1 | c.5635G>A p.E1879K | Missense Mutation (SNP) | VAF 87/315 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50006742; called by muse, mutect2, varscan2
- BRCA2 | c.7979A>G p.Y2660C | Missense Mutation (SNP) | VAF 74/156 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555286930, COSV66448549; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD4 | c.2094C>G p.F698L | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.066); catalogued as COSV54582620; called by muse, mutect2, varscan2
- BRINP2 | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV100838529, COSV64175535; called by muse, mutect2, varscan2
- C7 | c.1547A>G p.K516R | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100495485; called by muse, mutect2, varscan2
- CABCOCO1 | c.400A>G p.T134A | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV57591816; called by muse, mutect2, varscan2
- CACNA1F | c.2449G>C p.E817Q | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT tolerated (0.18); PolyPhen benign (0.167); catalogued as COSV59903133; called by muse, mutect2, varscan2
- CALN1 | c.39G>T p.K13N (on ENST00000329008 / NM_001017440.3; = p.K55N on NM_031468.4) | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV61120687; called by muse, mutect2, varscan2
- CBLL2 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 92/156 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV60368440; called by muse, mutect2, varscan2
- CD101 | c.3003G>C p.L1001F | Missense Mutation (SNP) | VAF 93/326 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV56716223; called by muse, mutect2, varscan2
- CD5L | c.955G>T p.E319* | Nonsense Mutation (SNP) | VAF 42/131 reads (32%) | catalogued as COSV63821141; called by muse, mutect2, varscan2
- CDC6 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 106/372 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.546); catalogued as COSV52929842; called by muse, mutect2, varscan2
- CDC7 | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52309392, COSV52311739; called by muse, mutect2, varscan2
- CDH7 | c.1114G>T p.D372Y | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV59881844; called by muse, mutect2, varscan2
- CENPP | c.199C>G p.L67V | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as COSV65037211; called by muse, mutect2, varscan2
- CEP164 | c.3257A>G p.K1086R | Missense Mutation (SNP) | VAF 116/266 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.541); catalogued as COSV54038535; called by muse, mutect2, varscan2
- CHMP5 | c.293C>G p.S98C | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV56302538; called by muse, mutect2, varscan2
- CHRNA7 | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60967947; called by muse, mutect2, varscan2
- CLCN6 | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV56738050, COSV56738623; called by muse, mutect2, varscan2
- CLSPN | c.3144G>C p.M1048I | Missense Mutation (SNP) | VAF 99/376 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV52047129; called by muse, mutect2, varscan2
- CMTR1 | c.1919A>G p.E640G | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65089542; called by muse, mutect2, varscan2
- CPA2 | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV55978789; called by muse, mutect2, varscan2
- CRB1 | c.2560G>A p.D854N | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100957705, COSV100957940; called by muse, mutect2
- CSMD3 | c.10828+1G>T p.X3610_splice (on ENST00000297405 / NM_001363185.1; = p.X3441_splice on NM_052900.3) | Splice Site (SNP) | VAF 55/254 reads (22%) | catalogued as COSV52108080; called by muse, mutect2, varscan2
- CTSA | c.1165-1G>C p.X389_splice | Splice Site (SNP) | VAF 26/77 reads (34%) | catalogued as COSV51940748; called by muse, mutect2, varscan2
- CUL9 | c.6388C>A p.R2130S | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.05); catalogued as COSV52725606; called by muse, mutect2, varscan2
- CYLC1 | c.1471G>C p.E491Q | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.858); catalogued as COSV61410052; called by muse, mutect2, varscan2
- DAB1 | c.1702G>A p.D568N (on ENST00000371231; = p.D535N on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as COSV64690380; called by muse, mutect2, varscan2
- DAPK1 | c.2161C>T p.P721S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.79); PolyPhen benign (0.196); catalogued as COSV63784504; called by muse, mutect2, varscan2
- DCLK3 | c.1825C>T p.Q609* | Nonsense Mutation (SNP) | VAF 71/200 reads (36%) | catalogued as COSV69362265; called by muse, mutect2, varscan2
- DDX11 | c.2419G>C p.E807Q (on ENST00000545668 / NM_152438.2; = p.E757Q on NM_004399.3) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52500294; called by muse, mutect2, varscan2
- DIO1 | c.681G>A p.K227= | Splice Region (SNP) | VAF 5/16 reads (31%) | catalogued as COSV59517431; called by muse, mutect2, varscan2
- DLC1 | c.3870G>T p.M1290I (on ENST00000276297 / NM_001348081.2; = p.M853I on NM_006094.5) | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV52291136; called by muse, mutect2, varscan2
- DNAH3 | c.10159G>T p.E3387* | Nonsense Mutation (SNP) | VAF 71/225 reads (32%) | catalogued as COSV54504699, COSV54505840; called by muse, mutect2, varscan2
- DNAH7 | c.2062C>T p.R688W | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs368478133; called by muse, mutect2, varscan2
- DNAJC10 | c.794C>G p.S265* | Nonsense Mutation (SNP) | VAF 20/76 reads (26%) | catalogued as COSV51135898; called by muse, mutect2, varscan2
- EFEMP1 | c.983G>C p.R328T | Missense Mutation (SNP) | VAF 93/325 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as COSV62615090; called by muse, mutect2, varscan2
- EFHC2 | c.1278C>T p.D426= | Splice Region (SNP) | VAF 16/32 reads (50%) | catalogued as COSV69552791; called by mutect2, varscan2
- EIF2B1 | c.120G>C p.E40D | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.048); catalogued as COSV57458205; called by muse, mutect2, varscan2
- EMP3 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 63/229 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV54285372; called by muse, mutect2, varscan2
- ENPP4 | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 80/302 reads (26%) | catalogued as COSV58088221, COSV58088735; called by muse, mutect2, varscan2
- ERI1 | c.1027C>A p.Q343K | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.036); catalogued as COSV51570595; called by muse, mutect2, varscan2
- EXOC2 | c.1851A>C p.L617= | Splice Region (SNP) | VAF 12/37 reads (32%) | catalogued as rs1425130072, COSV57861428; called by muse, mutect2, varscan2
- EZH1 | c.1785G>A p.W595* | Nonsense Mutation (SNP) | VAF 18/49 reads (37%) | catalogued as COSV101331423, COSV70548676; called by muse, mutect2, varscan2
- FAT2 | c.2950G>T p.E984* | Nonsense Mutation (SNP) | VAF 18/25 reads (72%) | catalogued as COSV55813968; called by muse, mutect2, varscan2
- FLAD1 | c.804G>A p.M268I | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1259036543, COSV52695892; called by muse, mutect2, varscan2
- FMN2 | c.2780C>A p.P927H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV60418172; called by muse, mutect2, varscan2
- FOLH1 | c.1443G>A p.L481= | Splice Region (SNP) | VAF 12/68 reads (18%) | catalogued as rs901180841, COSV57045915, COSV99922509; called by muse, mutect2, varscan2
- FOXK1 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV100194674; called by muse, mutect2, varscan2
- GH2 | c.385T>C p.Y129H | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.937); catalogued as COSV60426316; called by muse, mutect2, varscan2
- GOLGA3 | c.4480G>C p.E1494Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.025); catalogued as COSV52625951; called by muse, varscan2
- GRIK1 | c.2741C>T p.S914L | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV58711258; called by muse, mutect2, varscan2
- GTPBP4 | c.1724G>C p.R575P | Missense Mutation (SNP) | VAF 82/337 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52987143; called by muse, mutect2, varscan2
- HEPH | c.1192C>A p.H398N (on ENST00000343002; = p.H131N on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/99 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.053); catalogued as COSV57959310; called by muse, mutect2, varscan2
- HERC5 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV52037413; called by muse, mutect2, varscan2
- HOXC5 | c.139A>G p.I47V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.176); catalogued as COSV54536294; called by muse, mutect2, varscan2
- HTR1B | c.1087C>G p.L363V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64051125; called by muse, mutect2, varscan2
- HTR7 | c.1283C>G p.P428R | Missense Mutation (SNP) | VAF 60/220 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as COSV53283150, COSV99056850; called by muse, mutect2, varscan2
- IFIT2 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV51077967; called by muse, mutect2, varscan2
- IFT80 | c.1343G>T p.G448V | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV58445571; called by muse, mutect2, varscan2
- ING4 | c.733G>C p.E245Q (on ENST00000396807 / NM_001127582.2; = p.E244Q on NM_016162.4) | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV57523121; called by muse, mutect2, varscan2
- INPPL1 | c.2664del p.W888* | Frame Shift Del (DEL) | VAF 31/59 reads (53%) | catalogued as COSV99996717; called by mutect2, pindel, varscan2
- JPH4 | c.1154C>A p.A385E | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV58110343; called by muse, mutect2, varscan2
- KAT7 | c.566G>A p.G189D | Missense Mutation (SNP) | VAF 119/463 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52013184; called by muse, mutect2, varscan2
- KCNK9 | c.632A>C p.K211T | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV57278416; called by muse, mutect2, varscan2
- KCTD3 | c.2242G>T p.E748* | Nonsense Mutation (SNP) | VAF 15/108 reads (14%) | catalogued as COSV52064315; called by muse, mutect2, varscan2
- KLHL5 | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 46/150 reads (31%) | catalogued as COSV54671728; called by muse, mutect2, varscan2
- KMT2D | c.12620A>G p.K4207R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV56413128; called by muse, mutect2, varscan2
- L3MBTL4 | c.1606C>T p.R536W | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as rs898090328, COSV53113339; called by muse, mutect2, varscan2
- LEPR | c.1034G>T p.G345V | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60747820; called by muse, mutect2, varscan2
- LIPH | c.1055G>C p.R352T | Missense Mutation (SNP) | VAF 198/624 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV56182891, COSV56184664; called by muse, mutect2, varscan2
- LNPEP | c.1437G>A p.W479* | Nonsense Mutation (SNP) | VAF 28/77 reads (36%) | catalogued as rs1345311327, COSV51476318; called by muse, mutect2, varscan2
- LPGAT1 | c.757A>T p.I253L | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.127); catalogued as COSV65351109, COSV65352424; called by muse, mutect2, varscan2
- LRFN5 | c.1426C>G p.L476V | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53244066; called by muse, mutect2, varscan2
- LRRC32 | c.1615G>C p.E539Q | Missense Mutation (SNP) | VAF 20/273 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs564090585, COSV52631611, COSV52633361, COSV52634870; called by muse, mutect2
- LRRC37A3 | c.3658C>T p.Q1220* | Nonsense Mutation (SNP) | VAF 25/107 reads (23%) | catalogued as COSV58534336, COSV58534513; called by muse, mutect2, varscan2
- LRRC74A | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.544); catalogued as COSV53607985; called by muse, mutect2, varscan2
- LTF | c.1330C>A p.P444T | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV51605762; called by muse, mutect2, varscan2
- MAP2K1 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as rs727504819, COSV61068795; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MEFV | c.2246C>G p.S749C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.433); catalogued as rs104895171, CM077598; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MIA3 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as COSV60510085; called by muse, mutect2, varscan2
- MKRN3 | c.809G>T p.G270V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58808648; called by muse, mutect2, varscan2
- MMAA | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 74/234 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs374622922; called by muse, varscan2
- MME | c.1146C>A p.S382R | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV64706063; called by muse, mutect2, varscan2
- MME | c.1147C>A p.L383I | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV64706065; called by muse, mutect2, varscan2
- MTSS1 | c.151G>T p.A51S | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.247); catalogued as COSV61495044; called by muse, mutect2, varscan2
- MYO18B | c.4055C>G p.S1352C | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as rs1310389011, COSV59126064; called by muse, mutect2, varscan2
- MYO18B | c.4657C>G p.L1553V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as COSV59126074; called by muse, mutect2, varscan2
- MYPN | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV62731752; called by muse, mutect2, varscan2
- NCAPG | c.1259+1G>C p.X420_splice | Splice Site (SNP) | VAF 19/82 reads (23%) | catalogued as COSV52268727; called by muse, mutect2, varscan2
- NEB | c.9460G>T p.V3154F | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV50806214, COSV50814958, COSV99425534; called by muse, mutect2, varscan2
- NEK1 | c.3388G>A p.E1130K | Missense Mutation (SNP) | VAF 115/391 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.577); catalogued as rs780432086, COSV71454604; called by muse, mutect2, varscan2
- NFATC3 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 66/646 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV60471134; called by muse, mutect2
- NLGN1 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 80/268 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV64324150; called by muse, mutect2, varscan2
- NLGN4Y | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 78/322 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.094); catalogued as COSV59294258; called by muse, mutect2, varscan2
- NNT | c.3131C>G p.S1044C | Missense Mutation (SNP) | VAF 54/796 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV52922824; called by muse, mutect2
- NPAS3 | c.745A>T p.S249C (on ENST00000356141 / NM_001164749.2; = p.S217C on NM_022123.3) | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.594); catalogued as COSV60822963; called by muse, mutect2, varscan2
- NPR2 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as COSV61309291; called by muse, mutect2, varscan2
- NRG3 | c.980G>C p.R327P | Missense Mutation (SNP) | VAF 126/487 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64545807, COSV64552578, COSV64583332; called by muse, mutect2, varscan2
- NRIP1 | c.1288G>T p.G430C | Missense Mutation (SNP) | VAF 97/387 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV59655256; called by muse, mutect2, varscan2
- NUP153 | c.1601C>A p.S534Y | Missense Mutation (SNP) | VAF 51/201 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV50446307; called by muse, mutect2, varscan2
- OCA2 | c.1516G>T p.A506S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.283); catalogued as COSV62339109; called by muse, mutect2
- OPCML | c.621T>G p.D207E | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.759); catalogued as COSV59405378, COSV59406084; called by muse, mutect2, varscan2
- OPHN1 | c.110A>G p.K37R | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV62780399, COSV62780628; called by muse, mutect2, varscan2
- OR2W1 | c.128C>G p.T43R | Missense Mutation (SNP) | VAF 152/510 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV65851412; called by muse, mutect2, varscan2
- OR4D9 | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs12794170, COSV61434091; called by muse, mutect2, varscan2
- OR51D1 | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 200/641 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62913890, COSV62914209; called by muse, mutect2, varscan2
- OR56A3 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 160/443 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV61568562; called by muse, mutect2, varscan2
- OR56B4 | c.451A>G p.T151A | Missense Mutation (SNP) | VAF 102/295 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.097); catalogued as rs769726190, COSV57204030; called by muse, mutect2, varscan2
- OR5T1 | c.562C>G p.H188D | Missense Mutation (SNP) | VAF 141/544 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100479160, COSV57301712, COSV57304173; called by muse, mutect2, varscan2
- OR8I2 | c.689C>A p.A230E | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV56166679, COSV56168996; called by muse, mutect2, varscan2
- OR8J1 | c.589A>G p.T197A | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.547); catalogued as COSV57316689, COSV57320185; called by muse, mutect2, varscan2
- OR8S1 | c.540G>C p.E180D | Missense Mutation (SNP) | VAF 62/206 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV59599404; called by muse, mutect2, varscan2
- OSBPL2 | c.157C>G p.Q53E (on ENST00000313733 / NM_144498.4; = p.Q41E on NM_014835.4) | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.044); catalogued as COSV58215239, COSV58219785; called by muse, mutect2, varscan2
- PASK | c.3955C>T p.R1319C | Missense Mutation (SNP) | VAF 61/250 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.197); catalogued as rs367872189; called by muse, mutect2, varscan2
- PATJ | c.1706G>T p.R569M | Missense Mutation (SNP) | VAF 166/536 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100334605, COSV57156017; called by muse, mutect2, varscan2
- PBLD | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.079); catalogued as COSV53265330, COSV53265705; called by muse, mutect2, varscan2
- PCCB | c.859C>G p.P287A | Missense Mutation (SNP) | VAF 57/304 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.117); catalogued as COSV52443591; called by muse, mutect2, varscan2
- PCDH11X | c.2932A>G p.I978V | Missense Mutation (SNP) | VAF 104/200 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as COSV53444607; called by muse, mutect2, varscan2
- PCDH11X | c.3497C>G p.A1166G | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV53444640, COSV53499264; called by muse, mutect2, varscan2
- PCDHB3 | c.1660G>A p.A554T | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.022); catalogued as rs138158842; called by muse, mutect2, varscan2
- PDE3A | c.2001G>C p.L667= | Splice Region (SNP) | VAF 38/142 reads (27%) | catalogued as COSV62968471; called by muse, mutect2, varscan2
- PDZRN3 | c.2152T>A p.S718T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as COSV55191835; called by muse, mutect2, varscan2
- PGS1 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV99428058; called by muse, mutect2, varscan2
- PHACTR3 | c.833C>A p.S278Y | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV63025414; called by muse, mutect2, varscan2
- PIGG | c.1711G>A p.V571M (on ENST00000453061 / NM_001127178.3; = p.V563M on NM_017733.4) | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as rs770091281, COSV56316300; called by muse, mutect2, varscan2
- PIGZ | c.173A>G p.H58R | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53013099; called by muse, mutect2
- PLCH1 | c.4096T>G p.S1366A (on ENST00000340059 / NM_001130960.2; = p.S1358A on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.084); catalogued as COSV58187565; called by muse, mutect2
- PLCH1 | c.2945C>A p.S982* (on ENST00000340059 / NM_001130960.2; = p.S974* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 98/299 reads (33%) | catalogued as COSV58187582; called by muse, mutect2, varscan2
- PLXNA1 | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV52522476; called by muse, mutect2, varscan2
- POSTN | c.1157A>G p.D386G | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV65711935; called by muse, mutect2, varscan2
- PRDM2 | c.5048G>A p.R1683H | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as rs754582779, COSV52443129; called by muse, mutect2, varscan2
- PRMT8 | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as rs17852025, COSV54211686, COSV99039185; called by muse, mutect2, varscan2
- PRRC2B | c.6245G>A p.R2082Q | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs756081846, COSV100260894; called by muse, mutect2, varscan2
- PSMD1 | c.540C>A p.S180R | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV58076399, COSV58082306; called by muse, mutect2, varscan2
- RC3H1 | c.1921C>T p.H641Y | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.295); catalogued as COSV104383518, COSV51197942; called by muse, mutect2, varscan2
- RPL10L | c.10C>A p.R4S | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV53558692; called by muse, mutect2, varscan2
- RPN1 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs1308628417, COSV56189149; called by muse, mutect2, varscan2
- RYR3 | c.13567G>A p.E4523K (on ENST00000389232; = p.E4524K on NM_001036.6) | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as rs533061407, COSV66778823; called by muse, mutect2, varscan2
- SAP30BP | c.421C>T p.R141* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as rs762162999, COSV99502708; called by mutect2, varscan2
- SCN3A | c.4431G>C p.K1477N | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV51801987; called by muse, mutect2, varscan2
- SEMA6C | c.1465C>T p.R489* | Nonsense Mutation (SNP) | VAF 24/69 reads (35%) | catalogued as rs199674348, COSV59000254; called by muse, mutect2, varscan2
- SEPTIN12 | c.357G>C p.Q119H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.122); catalogued as COSV51615587; called by muse, mutect2, varscan2
- SIPA1L1 | c.1813C>G p.Q605E | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV62168545; called by muse, mutect2, varscan2
- SLC10A1 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV53681764, COSV53681902; called by muse, mutect2, varscan2
- SLC25A20 | c.421C>G p.Q141E | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV59802266; called by muse, mutect2, varscan2
- SLC28A2 | c.1855C>G p.Q619E | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV61663279, COSV61663581; called by muse, mutect2, varscan2
- SLC33A1 | c.233T>A p.L78Q | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1442047818, COSV63946728; called by muse, mutect2, varscan2
- SLC37A2 | c.1060G>A p.V354I | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs200568702, COSV53520565; called by muse, mutect2, varscan2
- SLC4A2 | c.2459C>T p.S820F | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52539200; called by muse, mutect2, varscan2
- SLITRK5 | c.2230C>T p.P744S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.014); catalogued as COSV61521123; called by muse, mutect2
- SOAT2 | c.353A>C p.Q118P | Missense Mutation (SNP) | VAF 65/254 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV56857055; called by muse, mutect2, varscan2
- SORBS1 | c.289G>A p.E97K (on ENST00000361941 / NM_001034954.2; = p.E65K on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs201169599, COSV53353445; called by muse, mutect2, varscan2
- SOX14 | c.640C>G p.P214A | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.374); catalogued as COSV60162489; called by muse, mutect2, varscan2
- SPNS3 | c.862G>T p.A288S | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV61069147; called by muse, mutect2, varscan2
- SPTBN4 | c.5435T>A p.L1812Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV58943934; called by muse, mutect2, varscan2
- SPTBN5 | c.6942C>G p.I2314M | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV58016723; called by muse, mutect2, varscan2
- STK10 | c.2161A>T p.I721F | Missense Mutation (SNP) | VAF 125/214 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51570698; called by muse, mutect2, varscan2
- SUPT20H | c.1664G>A p.G555E (on ENST00000350612 / NM_001014286.3; = p.G556E on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.405); catalogued as COSV62246866, COSV62249169; called by muse, mutect2, varscan2
- SZT2 | c.2333C>G p.S778* | Nonsense Mutation (SNP) | VAF 40/143 reads (28%) | catalogued as COSV100986947; called by muse, mutect2, varscan2
- TAAR5 | c.980C>A p.P327Q | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.019); catalogued as COSV57798497; called by muse, mutect2, varscan2
- TBC1D2B | c.1984G>A p.G662S | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56038504; called by muse, mutect2, varscan2
- TBC1D32 | c.429C>G p.I143M | Missense Mutation (SNP) | VAF 80/291 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV51536731, COSV51551905; called by muse, mutect2, varscan2
- TMEM132A | c.1094G>T p.R365L (on ENST00000453848 / NM_178031.3; = p.R366L on NM_017870.4) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV50001288; called by muse, mutect2, varscan2
- TMEM161B | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV56929405; called by muse, mutect2, varscan2
- TMEM17 | c.368C>A p.P123H | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59022372; called by muse, mutect2, varscan2
- TNC | c.3053A>G p.N1018S | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0.017); catalogued as rs61729548, COSV60780792; called by muse, mutect2, varscan2
- TRIM29 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100531513; called by muse, mutect2
- TTC7A | c.1690G>A p.D564N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99766112; called by muse, mutect2, varscan2
- TYR | c.756G>A p.M252I | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV54470520; called by muse, mutect2, varscan2
- UBAP1 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs766186080, COSV99902908; called by muse, mutect2, varscan2
- UBR2 | c.5166G>C p.K1722N | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV65749877; called by muse, mutect2
- UGGT2 | c.1616G>A p.R539Q | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); catalogued as rs1005656298, COSV65072501; called by muse, mutect2, varscan2
- UMOD | c.1808C>T p.P603L | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56773675; called by muse, mutect2, varscan2
- UPF2 | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 59/184 reads (32%) | catalogued as COSV62658510; called by muse, mutect2, varscan2
- USH2A | c.13363A>G p.T4455A | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.766); catalogued as rs768847990, COSV56330757; called by muse, mutect2, varscan2
- USP16 | c.113A>G p.K38R | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV57624029; called by muse, mutect2, varscan2
- USP29 | c.851A>T p.Q284L | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV54140088; called by muse, mutect2, varscan2
- USP43 | c.1185G>C p.E395D | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as rs756670307, COSV53299879; called by muse, mutect2, varscan2
- USP53 | c.1460A>T p.H487L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV56792465; called by muse, mutect2, varscan2
- VAC14 | c.541C>T p.R181* | Nonsense Mutation (SNP) | VAF 24/40 reads (60%) | catalogued as COSV55751200; called by muse, mutect2, varscan2
- VDAC1 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs1293289679, COSV54736671, COSV54738065; called by muse, mutect2, varscan2
- VPS13D | c.8733-1G>A p.X2911_splice | Splice Site (SNP) | VAF 25/86 reads (29%) | catalogued as COSV50622733; called by muse, mutect2, varscan2
- WDFY3 | c.10571G>A p.R3524Q | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs199672909; called by muse, mutect2, varscan2
- WDR41 | c.1378T>C p.*460Qext*12 | Nonstop Mutation (SNP) | VAF 47/141 reads (33%) | catalogued as COSV53732515; called by muse, mutect2, varscan2
- WDR88 | c.1170G>C p.W390C | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755030166, COSV63450706; called by muse, mutect2, varscan2
- XDH | c.2323-1G>C p.X775_splice | Splice Site (SNP) | VAF 88/354 reads (25%) | catalogued as COSV65147023; called by muse, mutect2, varscan2
- XIRP1 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100453445, COSV61137085; called by muse, mutect2, varscan2
- XIRP2 | c.499C>G p.Q167E (on ENST00000628543; = p.Q342E on NM_152381.6) | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.194); catalogued as COSV54683882; called by muse, mutect2, varscan2
- XIRP2 | c.4630A>T p.N1544Y (on ENST00000628543; = p.N1719Y on NM_152381.6) | Missense Mutation (SNP) | VAF 58/252 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV54683896; called by muse, mutect2, varscan2
- XRCC3 | c.51G>C p.K17N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as rs770709968, COSV99386170; called by muse, mutect2, varscan2
- ZBP1 | c.1067G>T p.G356V | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.48); catalogued as rs77921447, COSV59060296; called by muse, mutect2, varscan2
- ZDBF2 | c.7014G>C p.E2338D | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65622094; called by muse, mutect2, varscan2
- ZIK1 | c.1313G>T p.G438V | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.765); catalogued as COSV56736485; called by muse, mutect2, varscan2
- ZMYND15 | c.1648C>T p.P550S (on ENST00000433935 / NM_001136046.3; = p.P511S on NM_032265.2) | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.429); catalogued as rs766586490, COSV52639931; called by muse, mutect2, varscan2
- ZNF135 | c.1355C>T p.S452L (on ENST00000313434 / NM_001289401.2; = p.S464L on NM_003436.4) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs767883871, COSV57880247; called by muse, mutect2, varscan2
- ZNF250 | c.908G>T p.R303L | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV52968019; called by muse, mutect2, varscan2
- ZNF273 | c.535C>G p.Q179E | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV60397453; called by muse, mutect2, varscan2
- ZNF286A | c.545C>G p.S182* | Nonsense Mutation (SNP) | VAF 33/82 reads (40%) | catalogued as COSV101224748, COSV67845174; called by muse, mutect2, varscan2
- ZNF33B | c.933G>T p.R311S | Missense Mutation (SNP) | VAF 112/357 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.024); catalogued as COSV100847770, COSV63941896; called by muse, mutect2, varscan2
- ZNF461 | c.1685C>G p.A562G | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.077); catalogued as COSV64452928; called by muse, mutect2
- ZNF519 | c.993A>T p.R331S | Missense Mutation (SNP) | VAF 129/435 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.106); catalogued as COSV73913171; called by muse, mutect2, varscan2
- ZNF808 | c.665A>T p.Q222L | Missense Mutation (SNP) | VAF 112/483 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV63118750; called by muse, mutect2, varscan2
- CD47 | c.435dup p.V146Cfs*18 | Frame Shift Ins (INS) | VAF 7/37 reads (19%) | called by mutect2, pindel
- CDKN2A | c.328_341del p.W110Rfs*5 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- COL5A1 | c.4427dup p.G1477Wfs*5 | Frame Shift Ins (INS) | VAF 5/20 reads (25%) | called by mutect2, varscan2
- COL5A1 | c.4428delinsCC p.G1477Rfs*5 | Frame Shift Ins (INS) | VAF 8/29 reads (28%) | called by mutect2*, pindel, varscan2*
- DAGLA | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.972); called by muse, mutect2
- HOGA1 | c.665G>C p.G222A | Missense Mutation (SNP) | VAF 20/336 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- HOXB3 | c.399G>A p.M133I | Missense Mutation (SNP) | VAF 30/417 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- IGKV1D-43 | c.261T>A p.S87R | Missense Mutation (SNP) | VAF 100/427 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- KRTAP10-3 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 48/236 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- LTO1 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 44/631 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- MASTL | c.1877del p.P626Lfs*11 | Frame Shift Del (DEL) | VAF 16/75 reads (21%) | called by mutect2, pindel, varscan2
- NEPRO | c.825_826del p.I276Ffs*5 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel*, varscan2*
- OR10K1 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 18/486 reads (4%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.466); called by muse, mutect2
- OR13D1 | c.412G>A p.G138S | Missense Mutation (SNP) | VAF 22/636 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2
- OR8J3 | c.213_225del p.G72Sfs*7 | Frame Shift Del (DEL) | VAF 34/173 reads (20%) | called by mutect2, pindel, varscan2
- QRICH2 | c.4519G>A p.E1507K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- RASGRP4 | c.1063del p.L355Sfs*25 | Frame Shift Del (DEL) | VAF 5/15 reads (33%) | called by mutect2, varscan2
- RYR3 | c.13719del p.L4574Wfs*13 (on ENST00000389232; = p.L4575Wfs*13 on NM_001036.6) | Frame Shift Del (DEL) | VAF 28/136 reads (21%) | called by mutect2, pindel, varscan2
- SDR39U1 | c.661del p.S221Pfs*47 | Frame Shift Del (DEL) | VAF 17/70 reads (24%) | called by mutect2, pindel, varscan2
- USP9X | c.5815dup p.Y1939Lfs*16 | Frame Shift Ins (INS) | VAF 54/140 reads (39%) | called by mutect2, pindel, varscan2
- WNK2 | c.6303_6304del p.S2101Rfs*23 (on ENST00000297954 / NM_001282394.1; = p.S2064Rfs*23 on NM_006648.3) | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | called by mutect2, pindel, varscan2
- ZNF609 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- ADPRHL1 | c.138C>T p.L46= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs148683938; called by muse, mutect2, varscan2
- AIFM2 | c.198C>T p.F66= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV100325614, COSV57160313; called by muse, mutect2, varscan2
- AIFM3 | c.1167G>A p.V389= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV58997464; called by muse, mutect2, varscan2
- AMER3 | c.487C>T p.L163= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs780673224, COSV58465236; called by muse, mutect2, varscan2
- ANGPTL6 | c.1374C>G p.L458= | Silent (SNP) | VAF 35/302 reads (12%) | catalogued as COSV53461371; called by muse, mutect2, varscan2
- ATG16L2 | c.1086C>G p.L362= | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as COSV58361179; called by muse, mutect2, varscan2
- BCL11A | c.1218C>T p.D406= (on ENST00000335712 / NM_001365609.1; = p.D440= on NM_018014.4) | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs1436008474, COSV59624855; called by muse, mutect2, varscan2
- BCLAF1 | c.564A>G p.K188= | Silent (SNP) | VAF 20/289 reads (7%) | catalogued as COSV62140499; called by muse, mutect2
- BMP4 | c.585C>T p.L195= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV55415191; called by muse, mutect2, varscan2
- BRINP1 | c.1023C>A p.R341= | Silent (SNP) | VAF 35/144 reads (24%) | catalogued as COSV56292590; called by muse, mutect2, varscan2
- C2orf16 | c.3771T>C p.T1257= | Silent (SNP) | VAF 40/100 reads (40%) | catalogued as COSV62673944; called by muse, mutect2, varscan2
- CCDC163 | c.138C>T p.F46= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs143672401; called by muse, mutect2, varscan2
- COG7 | c.627G>A p.K209= | Silent (SNP) | VAF 38/143 reads (27%) | catalogued as COSV56149193; called by muse, mutect2, varscan2
- CPB1 | c.207C>T p.F69= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as rs758757426, COSV51571472; called by muse, mutect2, varscan2
- CTAGE1 | c.21T>G p.P7= | Silent (SNP) | VAF 33/132 reads (25%) | catalogued as COSV66942932; called by muse, mutect2, varscan2
- DDX11 | c.1671G>A p.L557= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV52500277; called by muse, mutect2, varscan2
- DUOX2 | c.3153C>T p.I1051= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV101199593; called by muse, mutect2
- DYNC2I1 | c.2340C>T p.S780= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV68103665; called by muse, mutect2, varscan2
- EPHA3 | c.1440A>G p.Q480= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as rs963604537, COSV100349933, COSV60693734, COSV60694993; called by muse, mutect2, varscan2
- FKBP8 | c.474C>T p.L158= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- FPGT | c.609T>G p.A203= | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as COSV63834736; called by muse, mutect2, varscan2
- GABBR2 | c.1194C>A p.I398= | Silent (SNP) | VAF 64/278 reads (23%) | catalogued as COSV52293984; called by muse, mutect2, varscan2
- GAREM1 | c.2079T>C p.S693= (on ENST00000269209 / NM_001242409.2; = p.S692= on NM_022751.3) | Silent (SNP) | VAF 38/894 reads (4%) | called by muse, mutect2
- GCNT3 | c.93C>T p.F31= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs767423891, COSV68531958; called by muse, mutect2, varscan2
- GHRHR | c.1230G>A p.T410= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs752346076, COSV58195464; called by muse, mutect2, varscan2
- GPBP1L1 | c.1374A>T p.S458= | Silent (SNP) | VAF 105/409 reads (26%) | catalogued as COSV51967084; called by muse, mutect2, varscan2
- GPR160 | c.288A>T p.L96= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as COSV63472582; called by muse, mutect2, varscan2
- IFI44 | c.399T>C p.L133= | Silent (SNP) | VAF 61/193 reads (32%) | catalogued as COSV66074168; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.321T>C p.S107= | Silent (SNP) | VAF 90/1098 reads (8%) | called by muse, mutect2
- IGSF8 | c.921G>C p.V307= | Silent (SNP) | VAF 60/184 reads (33%) | catalogued as COSV58757433; called by muse, mutect2, varscan2
- KIF18B | c.456C>G p.L152= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV59270864; called by muse, mutect2, varscan2
- MORC1 | c.549G>A p.L183= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV51714617, COSV51721540; called by muse, mutect2, varscan2
- MUC16 | c.30024A>G p.S10008= | Silent (SNP) | VAF 27/201 reads (13%) | catalogued as COSV67446616; called by muse, mutect2, varscan2
- NELL2 | c.711T>C p.L237= | Silent (SNP) | VAF 8/238 reads (3%) | called by muse, mutect2
- NPY1R | c.210G>A p.E70= | Silent (SNP) | VAF 59/215 reads (27%) | catalogued as COSV56713366, COSV56714448; called by muse, mutect2, varscan2
- OR10K2 | c.345G>A p.L115= | Silent (SNP) | VAF 132/457 reads (29%) | catalogued as COSV59220473, COSV59222152; called by muse, mutect2, varscan2
- OR4K14 | c.645C>G p.L215= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as COSV59292152; called by muse, mutect2, varscan2
- OR4P4 | c.918G>A p.L306= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV58920744, COSV58923543; called by muse, mutect2, varscan2
- PACC1 | c.84C>T p.D28= | Silent (SNP) | VAF 182/698 reads (26%) | catalogued as rs1276422389, COSV54786264, COSV54789100; called by muse, mutect2, varscan2
- PCDHGA12 | c.1302G>A p.T434= | Silent (SNP) | VAF 33/54 reads (61%) | catalogued as COSV52744306, COSV99340966, COSV99341962; called by muse, mutect2, varscan2
- PLXND1 | c.3309C>T p.A1103= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as rs752077323, COSV60709613; called by muse, mutect2, varscan2
- PSD3 | c.2424A>G p.G808= (on ENST00000440756; = p.G807= on NM_015310.4) | Silent (SNP) | VAF 82/190 reads (43%) | catalogued as COSV54066833, COSV54067923; called by muse, mutect2, varscan2
- RAB28 | c.633C>T p.N211= | Silent (SNP) | VAF 63/213 reads (30%) | catalogued as COSV56537952; called by muse, mutect2, varscan2
- RAI14 | c.1221A>G p.P407= | Silent (SNP) | VAF 33/192 reads (17%) | catalogued as COSV54289685; called by muse, mutect2, varscan2
- RASAL2 | c.267G>C p.T89= | Silent (SNP) | VAF 208/722 reads (29%) | catalogued as rs368634100; called by muse, mutect2, varscan2
- SFI1 | c.477G>A p.Q159= | Silent (SNP) | VAF 47/183 reads (26%) | catalogued as COSV66289783; called by muse, mutect2, varscan2
- SLC22A1 | c.1023G>A p.P341= | Silent (SNP) | VAF 194/554 reads (35%) | catalogued as rs757839673, COSV61451596; called by muse, mutect2, varscan2
- SLC35G3 | c.918A>T p.A306= | Silent (SNP) | VAF 78/265 reads (29%) | catalogued as COSV52010325; called by muse, mutect2, varscan2
- SLC9C1 | c.186A>G p.S62= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV59885272; called by muse, mutect2, varscan2
- SNRNP200 | c.1305C>T p.F435= | Silent (SNP) | VAF 5/81 reads (6%) | catalogued as COSV60490212; called by muse, mutect2
- SYNE1 | c.24015G>C p.L8005= (on ENST00000367255 / NM_182961.4; = p.L7934= on NM_033071.3) | Silent (SNP) | VAF 80/305 reads (26%) | catalogued as COSV54912851; called by muse, mutect2, varscan2
- TACR3 | c.93G>T p.G31= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV59198319; called by muse, mutect2, varscan2
- TCF7L2 | c.402C>T p.S134= | Silent (SNP) | VAF 29/129 reads (22%) | catalogued as COSV60502449; called by muse, mutect2, varscan2
- THNSL2 | c.660G>A p.L220= | Silent (SNP) | VAF 123/396 reads (31%) | catalogued as COSV59082014; called by muse, mutect2, varscan2
- TLR3 | c.1854G>A p.Q618= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as COSV57167532; called by muse, mutect2, varscan2
- TOMM70 | c.516G>A p.V172= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV52522286; called by muse, mutect2, varscan2
- TPH2 | c.135C>T p.D45= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as rs74510566, COSV61590555; called by muse, mutect2, varscan2
- TRAV24 | c.336T>C p.C112= | Silent (SNP) | VAF 28/82 reads (34%) | called by muse, mutect2, varscan2
- VCAN | c.2160C>A p.V720= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV54097476; called by muse, mutect2, varscan2
- WDCP | c.939C>G p.G313= | Silent (SNP) | VAF 7/125 reads (6%) | called by muse, mutect2
- ZNF688 | c.825C>T p.C275= | Silent (SNP) | VAF 4/53 reads (8%) | catalogued as COSV99794231; called by muse, mutect2
- ZSCAN1 | c.708G>A p.S236= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs764422436, COSV99991417; called by muse, mutect2, varscan2
- LINC02843 | n.458C>A | RNA (SNP) | VAF 15/62 reads (24%) | called by muse, mutect2, varscan2
- MIR1244-3 | n.80T>C | RNA (SNP) | VAF 62/264 reads (23%) | called by muse, mutect2, varscan2
- STARD7-AS1 | n.1422G>A | RNA (SNP) | VAF 12/54 reads (22%) | catalogued as rs1323362390; called by mutect2, varscan2
- TTN | c.10360+1143A>G | Intron (SNP) | VAF 69/349 reads (20%) | catalogued as COSV59899816; called by muse, mutect2, varscan2
- WNK1 | c.2140-3089A>T | Intron (SNP) | VAF 19/59 reads (32%) | catalogued as COSV60026066; called by muse, mutect2, varscan2
